Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A3AQ, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A3AQ-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Consultation Report

Patient Name:

MRN:

DOB:

Gender:

HCN:

Ordering MD:

Copy To:

Service:

Visit #:

Location:

Facility:

Accession #:

Collected:

Received:

Reported:

Specimen(s) Received

1. Thyroid: TOTAL THYROID STICH MARKS UPPER POLE RIGHT LOBE

Diagnosis

Multifocal papillary carcinoma, dominant mixed classical and follicular variant, 1.3 cm, left; mild follicular nodular disease and chronic lymphocytic thyroiditis: Thyroid

No pathological diagnosis: Lymph nodes, 2, isthmus

No pathological diagnosis: Lymph node, 1, left perithyroidal

-Total thyroidectomy specimen

Synoptic Data

Procedure:	Total thyroidectomy
Received:	Fresh
Specimen Integrity:	Intact
Specimen Size:	Right lobe:
	4.5 cm
	2.6 cm
	1.3 cm
	Left lobe:
	3.9 cm
	2.5 cm
	1.8 cm
	Isthmus +/- pyramidal lobe:
	1.7 cm
	1.2 cm
	0.5 cm
Specimen Weight:	15.1 g
Tumor Focality:	Multifocal, bilateral
	Multifocal, midline (isthmus)
	----- DOMINANT TUMOR -----
Tumor Laterality:	Left lobe

1CD-0-3

carcinoma, papillary, thyroid 8260/3

Site: thyroid, NOS C73.9

fw
10/21/11

[page 2 of 3]
Tumor Size: Greatest dimension: 1.3cm
Additional dimension: 1.0 cm
Additional dimension: 0.9 cm

Histologic Type: Papillary carcinoma, classical (usual)
Papillary carcinoma, follicular variant *per TSS, follicular variant 499%*
Classical (papillary) architecture
Follicular architecture
Classical cytomorphology

Histologic Grade: Not applicable

Margins: Margins uninvolved by carcinoma
Distance of invasive carcinoma to closest margin: 0.1mm

Tumor Capsule: Partially encapsulated

Tumor Capsular Invasion: Present, extent minimal

Lymph-Vascular Invasion: Not identified

Perineural Invasion: Not identified

Extrathyroidal Extension: Not identified

----- SECOND TUMOR -----

Tumor Laterality: Left lobe

Tumor Size: Greatest dimension: 1.0cm
Additional dimensions: 0.8 cm

Histologic Type: Papillary carcinoma, classical (usual)
Papillary carcinoma, follicular variant
Papillary carcinoma, microcarcinoma (occult, small or microscopic) variant
Classical (papillary) architecture
Follicular architecture
Classical cytomorphology

Histologic Grade: Not applicable

Margins: Margins uninvolved by carcinoma

Tumor Capsule: Partially encapsulated

Tumor Capsular Invasion: Present, extent minimal

Lymph-Vascular Invasion: Not identified

Perineural Invasion: Not identified

Extrathyroidal Extension: Not identified

TNM Descriptors: m (multiple primary tumors)
pT1b: Tumor more than 1 cm but not more than 2 cm in greatest dimension, limited to the thyroid

Primary Tumor (pT):

Regional Lymph Nodes (pN): pN0: No regional lymph node metastasis
Number of regional lymph nodes examined: 3
Number of regional lymph nodes involved: 0

Distant Metastasis (pM): Not applicable

Additional Pathologic Findings: Adenomatoid nodule(s) or Nodular follicular disease
Thyroiditis, other: chronic lymphocytic thyroiditis
Other: additional papillary microcarcinomas: 0.5 cm (classical variant, right lobe), 0.1 cm (follicular variant, isthmus) and 0.1 cm (oncocytic follicular variant, left)

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

Electronically verified by:
MD

Clinical History

Papillary thyroid carcinoma

Gross Description

The specimen labeled with the patient's name and as "Thyroid: Total thyroid stitch marks upper pole right lobe" consists of a

[page 3 of 3]
thyroid gland that is oriented with a stitch and weighs 15.1 g. The right lobe measures 4.5 cm SI x 2.6 cm ML x 1.3 cm AP, the left lobe measures 3.9 cm SI x 2.5 cm ML x 1.8 cm AP and the isthmus measures 1.7 cm SI x 1.2 cm ML x 0.5 cm AP. The external surfaces have fibrous adhesions and are painted with silver nitrate. No parathyroid glands or no lymph nodes are identified grossly. The upper and lower pole of the left lobe contains two well delineated nodule(s) that measure 1.0 cm SI x 0.8 cm ML x 0.7 cm AP and 1.3 cm SI x 1.0 cm ML x 0.9 cm AP. The remainder of the thyroid tissue is unremarkable. Sections of left lower lobe nodule and normal tissue are stored frozen. The remainder of the specimen is submitted as follows:

- 1A-E right lobe, superior to inferior
- 1F-G isthmus
- 1H-O left lobe, superior to inferior
-

Source: NCI Genomic Data Commons file f1eaddb4-68bd-4748-ae01-0f143d33fbf1 (TCGA-EM-A3AQ.2925FDE2-F80E-4B19-A634-F7A5A341A69A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).